Somatic mutation profile of tumor specimen TCGA-DD-A4NV-01A (aliquot TCGA-DD-A4NV-01A-11D-A30V-10) from TCGA case TCGA-DD-A4NV, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G1; Age at diagnosis: 61.4 years (22,438 days).
Specimen TCGA-DD-A4NV-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 49c06b99-7526-40d9-8cb4-359777a9783c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A4NV-10A (Blood Derived Normal), aliquot TCGA-DD-A4NV-10A-01D-A30V-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2ada0883-7e72-4321-8067-fa60bc56e6c9

The open-access MAF lists 129 somatic variants for this specimen: 102 protein-altering or splice-affecting, 27 silent.
By variant classification: Missense Mutation 91, Silent 27, Nonsense Mutation 4, In Frame Del 2, Frame Shift Del 2, Splice Site 1, Frame Shift Ins 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS10 | c.2513C>G p.S838W | Missense Mutation (SNP) | VAF 36/131 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as rs1389991838, COSV54353727, COSV54356224; called by muse, mutect2, varscan2
- AKAP13 | c.7231A>G p.T2411A (on ENST00000394518 / NM_007200.5; = p.T2415A on NM_006738.6) | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.8); catalogued as COSV63462324; called by muse, mutect2, varscan2
- AMZ2 | c.923A>G p.Y308C | Missense Mutation (SNP) | VAF 9/40 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV63083318; called by muse, mutect2, varscan2
- ANK2 | c.9262C>G p.P3088A | Missense Mutation (SNP) | VAF 14/51 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52169904; called by muse, mutect2, varscan2
- ARID5B | c.1531A>T p.R511* | Nonsense Mutation (SNP) | VAF 16/150 reads (11%) | catalogued as COSV54423376; called by muse, mutect2
- ARMC9 | c.346C>T p.P116S | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.248); catalogued as COSV63021921; called by muse, mutect2, varscan2
- ATG10 | c.446C>T p.T149M | Missense Mutation (SNP) | VAF 11/161 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.863); catalogued as rs548892230, COSV56423393; called by muse, mutect2
- ATM | c.521T>G p.L174R | Missense Mutation (SNP) | VAF 62/262 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV53752856; called by muse, mutect2, varscan2
- ATP2B4 | c.1711G>C p.V571L | Missense Mutation (SNP) | VAF 33/232 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0.045); catalogued as COSV58179752; called by muse, mutect2, varscan2
- ATP7B | c.1630C>G p.Q544E | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT tolerated (0.86); PolyPhen benign (0.006); catalogued as CM970137, COSV54440128; called by muse, mutect2
- ATP8B3 | c.1748G>A p.R583H | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs371318224; called by muse, mutect2, varscan2
- BAHCC1 | c.7114G>A p.D2372N | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.977); catalogued as rs782091307, COSV57028676; called by muse, mutect2, varscan2
- BCL3 | c.665G>A p.R222Q | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0); catalogued as rs763828094, COSV51234392; called by muse, mutect2, varscan2
- CAMK2A | c.640T>C p.W214R | Missense Mutation (SNP) | VAF 9/170 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV62246762; called by muse, mutect2
- CAPZA1 | c.136C>G p.L46V | Missense Mutation (SNP) | VAF 25/99 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV54145962; called by muse, mutect2, varscan2
- CCN3 | c.389A>G p.Q130R | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.03); PolyPhen benign (0.255); catalogued as COSV52384313; called by muse, mutect2, varscan2
- CDH15 | c.1531C>T p.P511S | Missense Mutation (SNP) | VAF 9/44 reads (20%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.515); catalogued as rs1419856684, COSV57025343; called by muse, mutect2, varscan2
- CHPF2 | c.2292T>A p.F764L | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as COSV50392782; called by muse, mutect2
- CHSY3 | c.1337T>A p.L446Q | Missense Mutation (SNP) | VAF 7/173 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV59280307; called by muse, mutect2
- CYP2W1 | c.400C>T p.H134Y | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.699); catalogued as rs778191648, COSV58270571; called by muse, mutect2, varscan2
- DCAF12L1 | c.1165G>A p.A389T | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs762351703, COSV64422075; called by muse, mutect2
- DENND3 | c.1444C>A p.P482T | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0.003); catalogued as rs556706834, COSV52803720; called by muse, mutect2, varscan2
- DHX29 | c.857_860del p.N286Sfs*11 | Frame Shift Del (DEL) | VAF 21/127 reads (17%) | catalogued as rs765664094; called by mutect2, pindel, varscan2
- DMTF1 | c.2262A>T p.E754D | Missense Mutation (SNP) | VAF 48/263 reads (18%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as COSV57538763; called by muse, mutect2, varscan2
- DNAJC13 | c.1322G>T p.G441V | Missense Mutation (SNP) | VAF 40/217 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53453215; called by muse, mutect2, varscan2
- DSCAM | c.3886A>T p.T1296S | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.965); catalogued as COSV68029762; called by muse, mutect2, varscan2
- DSCAM | c.1937A>G p.D646G | Missense Mutation (SNP) | VAF 34/125 reads (27%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.997); catalogued as COSV68029765; called by muse, mutect2, varscan2
- EEPD1 | c.1333A>G p.I445V | Missense Mutation (SNP) | VAF 19/151 reads (13%) | SIFT tolerated (0.85); PolyPhen benign (0.001); catalogued as COSV54199991; called by muse, mutect2, varscan2
- EGFL8 | c.485C>A p.T162K | Missense Mutation (SNP) | VAF 19/78 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV61248042; called by muse, mutect2, varscan2
- ELOVL2 | c.391A>C p.I131L | Missense Mutation (SNP) | VAF 49/165 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV61155971; called by muse, mutect2, varscan2
- ERCC6 | c.3949C>T p.H1317Y | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as rs937200876, COSV63391584; called by muse, mutect2, varscan2
- FASN | c.884C>T p.T295I | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60756931; called by muse, mutect2, varscan2
- GRAP2 | c.821G>A p.R274Q | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.743); catalogued as rs774420692, COSV59995908; called by muse, mutect2, varscan2
- H4C11 | c.7G>A p.G3S | Missense Mutation (SNP) | VAF 48/194 reads (25%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.796); catalogued as rs918002664, COSV61827195, COSV61827277; called by muse, mutect2, varscan2
- HTR1F | c.437T>A p.I146K | Missense Mutation (SNP) | VAF 4/73 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as COSV100137993; called by muse, mutect2
- ITGBL1 | c.1110C>A p.D370E | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.142); catalogued as COSV66009192; called by muse, mutect2, varscan2
- L1CAM | c.1820T>C p.L607S | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.052); catalogued as COSV62828740; called by muse, mutect2, varscan2
- LETMD1 | c.132G>T p.K44N | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.205); catalogued as COSV50398110; called by muse, mutect2, varscan2
- MAN2A2 | c.283A>G p.N95D | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.519); catalogued as COSV64638782; called by muse, mutect2
- MAPK6 | c.1826A>G p.Q609R | Missense Mutation (SNP) | VAF 22/379 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.011); catalogued as rs766643187, COSV55930597; called by muse, mutect2
- MARF1 | c.1183G>A p.D395N | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60025305; called by muse, mutect2, varscan2
- MAST3 | c.2741G>C p.G914A | Missense Mutation (SNP) | VAF 4/46 reads (9%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.751); catalogued as COSV53222700; called by muse, mutect2
- MFGE8 | c.886T>A p.S296T | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV51556727; called by muse, mutect2, varscan2
- MFN1 | c.1555G>A p.D519N | Missense Mutation (SNP) | VAF 27/192 reads (14%) | SIFT tolerated (0.2); PolyPhen benign (0.16); catalogued as COSV54940537; called by muse, mutect2, varscan2
- MMP13 | c.121C>T p.R41C | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as rs767829684, COSV52823318; called by muse, mutect2, varscan2
- NBAS | c.4103G>A p.R1368K | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV55717548, COSV55727054; called by mutect2, varscan2
- NHP2 | c.326C>T p.P109L | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51071059; called by muse, mutect2, varscan2
- NUP205 | c.3959A>C p.D1320A | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.51); PolyPhen benign (0.192); catalogued as COSV53661311; called by muse, mutect2, varscan2
- NXPH4 | c.821T>C p.F274S | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV61074469; called by muse, mutect2, varscan2
- NYAP1 | c.689G>C p.S230T | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.31); PolyPhen benign (0.021); catalogued as COSV55719764; called by muse, mutect2, varscan2
- OPLAH | c.554G>A p.R185H | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs868953913, COSV70678441; called by muse, mutect2, varscan2
- OR4M1 | c.334A>G p.M112V | Missense Mutation (SNP) | VAF 24/201 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.081); catalogued as COSV60059490; called by muse, mutect2, varscan2
- OR8K1 | c.131C>A p.T44K | Missense Mutation (SNP) | VAF 23/114 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.835); catalogued as COSV54403163; called by muse, mutect2, varscan2
- PCLO | c.2396C>G p.S799C | Missense Mutation (SNP) | VAF 15/233 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.634); catalogued as rs1428811438, COSV61615815, COSV61644737; called by muse, mutect2
- POLR2B | c.2851C>T p.Q951* | Nonsense Mutation (SNP) | VAF 17/164 reads (10%) | catalogued as COSV58901331; called by muse, mutect2, varscan2
- POU3F4 | c.352C>T p.P118S | Missense Mutation (SNP) | VAF 8/148 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0.028); catalogued as COSV64539822; called by muse, mutect2
- PRIMPOL | c.1186G>T p.G396* | Nonsense Mutation (SNP) | VAF 73/229 reads (32%) | catalogued as COSV59249342; called by muse, mutect2, varscan2
- PRRG3 | c.361C>A p.L121I | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as COSV64851227; called by muse, mutect2, varscan2
- PSG11 | c.110T>C p.M37T | Missense Mutation (SNP) | VAF 50/223 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1058223; called by muse, mutect2, varscan2
- RAB1A | c.82C>A p.L28I | Missense Mutation (SNP) | VAF 144/570 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV53198116; called by muse, mutect2, varscan2
- RET | c.611A>G p.Y204C | Missense Mutation (SNP) | VAF 6/33 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV60699410; called by muse, mutect2, varscan2
- RFPL4B | c.375T>A p.D125E | Missense Mutation (SNP) | VAF 5/54 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.014); catalogued as COSV71437490; called by muse, mutect2
- RIF1 | c.1375C>T p.P459S | Missense Mutation (SNP) | VAF 44/177 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.821); catalogued as COSV54619220; called by muse, mutect2, varscan2
- RNF19A | c.1912G>T p.D638Y | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.498); catalogued as COSV61993781; called by muse, mutect2, varscan2
- RNF212 | c.31T>A p.F11I | Missense Mutation (SNP) | VAF 26/93 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.503); catalogued as COSV61365074; called by muse, mutect2, varscan2
- RRP15 | c.140-1G>A p.X47_splice | Splice Site (SNP) | VAF 20/182 reads (11%) | catalogued as COSV65118208; called by muse, mutect2
- SDF4 | c.1051G>A p.V351M | Missense Mutation (SNP) | VAF 18/72 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as rs778039481, COSV55420112; called by muse, mutect2, varscan2
- SEC13 | c.548C>T p.A183V (on ENST00000350697 / NM_183352.3; = p.A186V on NM_030673.4) | Missense Mutation (SNP) | VAF 16/104 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61601956; called by muse, mutect2, varscan2
- SEMA3A | c.770C>A p.S257Y | Missense Mutation (SNP) | VAF 12/102 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.397); catalogued as COSV54874754, COSV54875795; called by muse, mutect2, varscan2
- SFI1 | c.2256C>T p.G752= (on ENST00000400288 / NM_001007467.3; = p.G721= on NM_014775.4) | Splice Region (SNP) | VAF 13/61 reads (21%) | catalogued as COSV63475547; called by muse, mutect2, varscan2
- SHANK2 | c.3697G>A p.G1233R | Missense Mutation (SNP) | VAF 14/77 reads (18%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.653); catalogued as COSV53605024; called by muse, mutect2, varscan2
- SLC39A10 | c.2475T>G p.I825M | Missense Mutation (SNP) | VAF 17/183 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV56771560; called by muse, mutect2
- SLIT1 | c.4135G>A p.G1379S | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.026); catalogued as rs373006664; called by muse, mutect2, varscan2
- SLITRK4 | c.1054C>A p.P352T | Missense Mutation (SNP) | VAF 38/105 reads (36%) | SIFT tolerated (0.85); PolyPhen benign (0.244); catalogued as COSV62024783; called by muse, mutect2, varscan2
- SMG5 | c.881T>C p.L294P | Missense Mutation (SNP) | VAF 11/154 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62436130; called by muse, mutect2
- SMG6 | c.2143C>T p.R715C | Missense Mutation (SNP) | VAF 17/71 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as rs752531928, COSV53969996; called by muse, mutect2, varscan2
- SNX11 | c.412T>A p.C138S | Missense Mutation (SNP) | VAF 7/52 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV63658686; called by muse, mutect2, varscan2
- SPACA9 | c.353C>G p.P118R | Missense Mutation (SNP) | VAF 29/141 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100052040, COSV53768806; called by muse, mutect2, varscan2
- STK17B | c.599A>G p.E200G | Missense Mutation (SNP) | VAF 9/117 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as COSV55828905; called by muse, mutect2
- STYXL2 | c.1560G>T p.E520D | Missense Mutation (SNP) | VAF 56/179 reads (31%) | SIFT tolerated (0.05); PolyPhen benign (0.24); catalogued as COSV54806739; called by muse, mutect2, varscan2
- SUPT4H1 | c.290T>A p.I97N | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.622); catalogued as COSV56643091; called by muse, mutect2, varscan2
- TBL2 | c.828G>T p.K276N | Missense Mutation (SNP) | VAF 26/136 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV59787452; called by muse, mutect2, varscan2
- TCF7L2 | c.1253C>A p.S418Y (on ENST00000355995 / NM_001367943.1; = p.S395Y on NM_030756.5) | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53342827, COSV99526898; called by muse, mutect2, varscan2
- TENM2 | c.3007G>A p.A1003T (on ENST00000518659 / NM_001122679.2; = p.A771T on NM_001080428.3) | Missense Mutation (SNP) | VAF 21/106 reads (20%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.645); catalogued as rs770204553, COSV69134016; called by muse, mutect2, varscan2
- TFAP2B | c.208T>G p.F70V | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.027); catalogued as COSV53828891; called by muse, mutect2, varscan2
- TMEM132B | c.714G>T p.W238C | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.891); catalogued as COSV54751124, COSV54758150; called by muse, mutect2, varscan2
- TMEM132B | c.715G>T p.E239* | Nonsense Mutation (SNP) | VAF 7/53 reads (13%) | catalogued as COSV54758159; called by muse, mutect2, varscan2
- TMEM63C | c.705A>T p.E235D | Missense Mutation (SNP) | VAF 23/108 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV53604984; called by muse, mutect2, varscan2
- TNN | c.1051C>G p.L351V | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.49); PolyPhen benign (0.001); catalogued as COSV53420975, COSV53429185; called by muse, mutect2, varscan2
- TRRAP | c.8908G>A p.V2970M (on ENST00000359863 / NM_001244580.1; = p.V2952M on NM_003496.3) | Missense Mutation (SNP) | VAF 35/172 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs1399228248, COSV62847495; called by muse, mutect2, varscan2
- USP1 | c.1516T>C p.C506R | Missense Mutation (SNP) | VAF 18/146 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60574305, COSV60574812; called by muse, mutect2, varscan2
- USP4 | c.2653T>C p.Y885H | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); catalogued as COSV55538093; called by muse, mutect2
- USP6NL | c.1922A>C p.N641T | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.115); catalogued as COSV53212878; called by muse, mutect2
- ZFYVE16 | c.770A>G p.H257R | Missense Mutation (SNP) | VAF 16/251 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV62016158; called by muse, mutect2
- ZNF212 | c.622G>A p.A208T | Missense Mutation (SNP) | VAF 7/86 reads (8%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV60025409; called by muse, mutect2
- ZNF385B | c.706G>T p.D236Y | Missense Mutation (SNP) | VAF 50/183 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.813); catalogued as COSV61178965; called by muse, mutect2, varscan2
- ZNF76 | c.386G>T p.G129V | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.046); catalogued as COSV57591805; called by muse, mutect2, varscan2
- ZNF804B | c.2614C>A p.Q872K | Missense Mutation (SNP) | VAF 34/261 reads (13%) | SIFT tolerated (0.83); PolyPhen benign (0.022); catalogued as COSV60827610, COSV60831178; called by muse, mutect2, varscan2
- ATP6V1A | c.1119_1127del p.P375_Y377del | In Frame Del (DEL) | VAF 16/100 reads (16%) | called by mutect2, pindel, varscan2
- C6orf62 | c.69dup p.E24Rfs*5 | Frame Shift Ins (INS) | VAF 14/128 reads (11%) | called by mutect2, pindel, varscan2
- CLGN | c.1493_1509del p.K498Rfs*3 | Frame Shift Del (DEL) | VAF 21/85 reads (25%) | called by mutect2, pindel, varscan2
- COL4A4 | c.1115_1125delinsGG p.P372_P375delinsR | In Frame Del (DEL) | VAF 18/109 reads (17%) | called by pindel, varscan2*
- ALDOA | c.708C>T p.G236= (on ENST00000642816 / NM_001243177.4; = p.G182= on NM_184041.5) | Silent (SNP) | VAF 19/59 reads (32%) | catalogued as COSV57633152; called by muse, mutect2, varscan2
- ANKIB1 | c.2856A>G p.S952= | Silent (SNP) | VAF 14/116 reads (12%) | catalogued as rs374467744; called by muse, mutect2, varscan2
- BLM | c.3705C>A p.V1235= | Silent (SNP) | VAF 40/181 reads (22%) | catalogued as COSV61925121; called by muse, mutect2, varscan2
- CENATAC | c.153T>G p.A51= | Silent (SNP) | VAF 7/44 reads (16%) | catalogued as COSV57723092; called by muse, mutect2, varscan2
- CLEC3B | c.537G>A p.A179= | Silent (SNP) | VAF 14/82 reads (17%) | catalogued as COSV56109973; called by muse, mutect2, varscan2
- DDX3X | c.1014C>T p.D338= (on ENST00000399959; = p.D339= on NM_001356.5) | Silent (SNP) | VAF 5/121 reads (4%) | catalogued as COSV101302378; called by muse, mutect2
- F8 | c.3435A>G p.P1145= | Silent (SNP) | VAF 16/121 reads (13%) | catalogued as COSV64275127; called by muse, mutect2, varscan2
- FASN | c.6543A>G p.Q2181= | Silent (SNP) | VAF 15/71 reads (21%) | catalogued as rs1265273432, COSV60756915; called by muse, mutect2, varscan2
- FAT2 | c.1095T>A p.A365= | Silent (SNP) | VAF 38/196 reads (19%) | catalogued as COSV55822911; called by muse, mutect2, varscan2
- GRIN2D | c.2448C>T p.I816= | Silent (SNP) | VAF 9/44 reads (20%) | catalogued as COSV53517687; called by muse, mutect2, varscan2
- IRS2 | c.2175C>T p.G725= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as rs781154356, COSV65479438; called by muse, mutect2, varscan2
- KCNU1 | c.690A>C p.I230= | Silent (SNP) | VAF 11/89 reads (12%) | catalogued as COSV67757385; called by muse, mutect2, varscan2
- MELTF | c.720G>A p.T240= | Silent (SNP) | VAF 25/98 reads (26%) | catalogued as rs375237562; called by muse, mutect2, varscan2
- MPP7 | c.1017A>G p.E339= | Silent (SNP) | VAF 11/93 reads (12%) | catalogued as rs1242855948, COSV61734417; called by muse, mutect2, varscan2
- MYBPC2 | c.2277T>C p.P759= | Silent (SNP) | VAF 7/53 reads (13%) | catalogued as COSV63096869; called by muse, mutect2, varscan2
- NUDT12 | c.1317C>T p.F439= | Silent (SNP) | VAF 25/118 reads (21%) | catalogued as COSV50091421; called by muse, mutect2, varscan2
- OR13D1 | c.649C>T p.L217= | Silent (SNP) | VAF 33/144 reads (23%) | catalogued as COSV59514204; called by muse, mutect2, varscan2
- OR5D18 | c.459A>T p.G153= | Silent (SNP) | VAF 28/144 reads (19%) | catalogued as COSV61736748; called by muse, mutect2, varscan2
- OTP | c.174G>T p.L58= | Silent (SNP) | VAF 12/72 reads (17%) | catalogued as COSV60569223; called by muse, mutect2, varscan2
- OTUD7B | c.2529C>T p.F843= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as COSV64916683; called by muse, mutect2, varscan2
- PCDH1 | c.1842G>C p.L614= | Silent (SNP) | VAF 8/55 reads (15%) | catalogued as COSV54615620; called by muse, mutect2, varscan2
- PRSS1 | c.483G>A p.L161= | Silent (SNP) | VAF 19/367 reads (5%) | catalogued as COSV100297822; called by muse, mutect2
- RBP7 | c.339A>C p.G113= | Silent (SNP) | VAF 11/96 reads (11%) | catalogued as COSV53813291; called by muse, mutect2, varscan2
- SLC6A18 | c.1668C>G p.P556= | Silent (SNP) | VAF 19/97 reads (20%) | catalogued as COSV57252316; called by muse, mutect2, varscan2
- SLIT1 | c.24G>A p.G8= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV56591949; called by muse, mutect2
- VPS13C | c.11233A>C p.R3745= (on ENST00000644861 / NM_020821.3; = p.R3702= on NM_017684.5) | Silent (SNP) | VAF 27/96 reads (28%) | catalogued as COSV51278130; called by muse, mutect2, varscan2
- ZFP14 | c.945G>A p.K315= | Silent (SNP) | VAF 16/65 reads (25%) | catalogued as COSV54201560, COSV54203163; called by muse, mutect2, varscan2
